Gene-level copy-number profile of specimen HCM-CSHL-0433-C24-85A from HCMI case HCM-CSHL-0433-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.1 years (19,015 days).
Specimen HCM-CSHL-0433-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2b6e2469-96e5-40c8-a341-d772b02d6236.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0433-C24-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/195c6589-2b98-4326-a8f0-d78e78358015

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,905; copy number 2: 48,976; copy number 3: 2,010; copy number 4: 989; copy number 5: 34.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:34,190,471–34,249,958, 4 genes, copy number 5: AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr17:32,007,872–32,053,504, 2 genes, copy number 5 (within-gene range 4–5): LRRC37B, AC090616.4.
- chr17:32,127,595–32,128,454, 1 gene, copy number 5: AC116407.2.
- chr17:47,253,827–47,941,410, 26 genes, copy number 5: ITGB3, AC068234.1, RNU7-186P, AC068234.2, THCAT158, EFCAB13, AC040934.1, MRPL45P2, NPEPPS, Y_RNA, AC025682.1, KPNB1, AC015674.1, TBKBP1, TBX21, OSBPL7, MRPL10, LRRC46, SCRN2, SP6, AC018521.3, AC018521.7, AC018521.5, SP2, SP2-AS1, AC018521.6.
- chr17:52,985,513–52,987,652, 1 gene, copy number 5: LINC02876.

Autosomal genes at a single copy (total copy number 1): 4,049. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
